Somatic mutation profile of tumor specimen C3L-01282-01 (aliquot CPT0077650006) from CPTAC case C3L-01282, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 64.1 years (23,414 days).
Specimen C3L-01282-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6fc6350-9ad5-4ff5-b8e4-6854d2af81d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01282-31 (Blood Derived Normal), aliquot CPT0080070001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9c79e0e-d26e-4dc0-9cdf-ce07ffdc952f

The open-access MAF lists 1,227 somatic variants for this specimen: 846 protein-altering or splice-affecting, 221 silent, 160 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 572, Silent 221, Frame Shift Del 167, Intron 88, Nonsense Mutation 33, Frame Shift Ins 31, RNA 23, 3'UTR 21, Splice Site 18, Splice Region 16, 5'UTR 12, 5'Flank 11.

Variants (750 of 1,227; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC092143.1 | c.1945G>A p.A649T | Missense Mutation (SNP) | VAF 170/554 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs267607163, CM100191, COSV59248281; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLCN5 | c.815A>G p.Y272C | Missense Mutation (SNP) | VAF 45/351 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs273585644, CM066756; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.1124A>G p.Y375C | Missense Mutation (SNP) | VAF 106/707 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs121913478, CM960653, COSV60640350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1699A>G p.K567E (on ENST00000521381 / NM_181523.3; = p.K297E on NM_181504.4) | Missense Mutation (SNP) | VAF 17/139 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV57123609; called by muse, mutect2, varscan2
- PIK3R2 | c.1690A>G p.K564E | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs886041602, COSV55847404; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.625G>T p.G209* | Nonsense Mutation (SNP) | VAF 50/241 reads (21%) | catalogued as rs765433422, COSV64294737, COSV99057830; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.741dup p.P248Tfs*5 | Frame Shift Ins (INS) | VAF 224/544 reads (41%) | catalogued as rs587782341, CI043805, COSV64288762; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AADACL3 | c.762del p.Q255Kfs*14 | Frame Shift Del (DEL) | VAF 44/156 reads (28%) | catalogued as rs746497630; called by mutect2, varscan2
- ABCA9 | c.3919del p.I1307Lfs*16 | Frame Shift Del (DEL) | VAF 12/102 reads (12%) | catalogued as rs1342264154; called by mutect2, pindel, varscan2
- ACTN1 | c.2598del p.Y867Tfs*78 | Frame Shift Del (DEL) | VAF 53/149 reads (36%) | catalogued as COSV99518346; called by mutect2, pindel, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 12/110 reads (11%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM8 | c.1281dup p.E428Rfs*17 | Frame Shift Ins (INS) | VAF 12/76 reads (16%) | catalogued as rs753471255; called by mutect2, varscan2
- ADGB | c.4585C>T p.R1529* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as rs1240602803, COSV58849886; called by muse, mutect2, varscan2
- ADGRL1 | c.1775G>A p.R592Q (on ENST00000340736 / NM_001008701.3; = p.R587Q on NM_014921.5) | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as rs372129747; called by muse, mutect2, varscan2
- AFG3L2 | c.2347C>T p.R783W | Missense Mutation (SNP) | VAF 107/383 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs200514577; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHNAK | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752058736, COSV57208461; called by muse, mutect2, varscan2
- AHNAK2 | c.7367C>T p.P2456L | Missense Mutation (SNP) | VAF 109/369 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as rs369383115; called by muse, mutect2, varscan2
- AMER2 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); catalogued as COSV63441571; called by muse, mutect2, varscan2
- AMOT | c.1414G>A p.V472I (on ENST00000371959 / NM_001113490.1; = p.V63I on NM_133265.3) | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT tolerated (0.92); PolyPhen benign (0.019); catalogued as rs41300179, COSV100495389; called by muse, mutect2, varscan2
- ANO10 | c.1839A>G p.I613M | Missense Mutation (SNP) | VAF 22/347 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1268397689; called by muse, mutect2
- AQP7 | c.700dup p.R234Pfs*61 | Frame Shift Ins (INS) | VAF 58/246 reads (24%) | catalogued as rs3215969; called by mutect2, varscan2
- ARHGEF40 | c.4544C>T p.P1515L | Missense Mutation (SNP) | VAF 63/197 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs747315393; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 31/214 reads (14%) | catalogued as COSV61389445; called by mutect2, pindel
- ARID4A | c.1266del p.D423Tfs*2 | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | catalogued as rs776520069; called by mutect2, varscan2
- ASXL2 | c.1694G>A p.S565N | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.15); catalogued as rs1411983226; called by muse, mutect2, varscan2
- ATG2A | c.3736C>A p.P1246T | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as rs1171984610; called by muse, mutect2, varscan2
- ATP13A3 | c.3461C>T p.A1154V | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV99755898; called by muse, mutect2, varscan2
- ATP9A | c.1742A>G p.N581S | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.491); catalogued as rs971331660; called by muse, mutect2
- BCKDK | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 64/223 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV99570933; called by muse, mutect2, varscan2
- BCORL1 | c.3671G>A p.R1224H | Missense Mutation (SNP) | VAF 49/241 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54397937; called by muse, mutect2, varscan2
- BCORL1 | c.5042dup p.G1682Rfs*4 | Frame Shift Ins (INS) | VAF 21/198 reads (11%) | catalogued as rs768244116, COSV54407680; called by mutect2, varscan2
- BMP1 | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as rs755275447, COSV60483462; called by muse, mutect2, varscan2
- BMP7 | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.013); catalogued as rs1178752029; called by muse, mutect2, varscan2
- BRCA1 | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.477); catalogued as rs587782770; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely benign; called by muse, mutect2, varscan2
- BRINP1 | c.1021C>A p.R341S | Missense Mutation (SNP) | VAF 160/566 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.931); catalogued as COSV56294487; called by muse, mutect2, varscan2
- C1orf105 | c.43A>G p.K15E | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1468910429; called by muse, mutect2, varscan2
- CACNA1A | c.4423G>A p.A1475T | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as rs1187916307, COSV64190595; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1B | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs576957409, COSV53137551; called by muse, mutect2, varscan2
- CACNA1E | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 39/390 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as rs866035995, COSV100704515; called by muse, mutect2
- CAMSAP1 | c.2294T>C p.I765T | Missense Mutation (SNP) | VAF 96/311 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs771017985; called by muse, mutect2, varscan2
- CAPNS1 | c.-15-3del | Splice Region (DEL) | VAF 26/251 reads (10%) | catalogued as rs754973381; called by pindel, varscan2
- CARD11 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV100712210; called by muse, mutect2
- CARD9 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 84/256 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.616); catalogued as rs770587024; called by muse, mutect2, varscan2
- CARMIL2 | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 53/274 reads (19%) | catalogued as rs758504087, COSV58026526; called by muse, mutect2, varscan2
- CCDC150 | c.1574A>G p.D525G | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs757827925; called by muse, mutect2, varscan2
- CCDC180 | c.4189G>T p.E1397* | Nonsense Mutation (SNP) | VAF 26/126 reads (21%) | catalogued as COSV63831055; called by muse, mutect2, varscan2
- CCDC74A | c.189_191dup p.Q63dup | In Frame Ins (INS) | VAF 28/221 reads (13%) | catalogued as rs747022309; called by mutect2, varscan2
- CCPG1 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs745580071, COSV51243940; called by muse, mutect2, varscan2
- CCR4 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 77/233 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs752494781, COSV58384563; called by muse, mutect2, varscan2
- CCRL2 | c.373A>G p.T125A | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as rs764368189, COSV62193370; called by muse, mutect2
- CD200R1L | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.492); catalogued as COSV68004906; called by muse, mutect2
- CDON | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1012612060, COSV99701222; called by muse, mutect2, varscan2
- CDON | c.23T>C p.L8S | Missense Mutation (SNP) | VAF 48/538 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as COSV99701084; called by muse, mutect2
- CHD2 | c.4714G>A p.V1572M | Missense Mutation (SNP) | VAF 60/196 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs755267457; called by muse, mutect2, varscan2
- CHIA | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as rs201556508, COSV58473904; called by muse, mutect2, varscan2
- CILP2 | c.1922G>A p.G641D | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1420415587; called by muse, mutect2
- CKLF | c.447del p.E150Kfs*? (on ENST00000264001 / NM_016951.4; = p.E65Kfs*? on NM_016326.3) | Frame Shift Del (DEL) | VAF 52/248 reads (21%) | catalogued as rs754415052; called by mutect2, varscan2
- CLBA1 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 128/466 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV66348241; called by muse, mutect2, varscan2
- COL4A2 | c.2414del p.P805Lfs*15 | Frame Shift Del (DEL) | VAF 28/110 reads (25%) | catalogued as rs1324194272; called by mutect2, pindel, varscan2
- CPSF2 | c.2041del p.S681Vfs*36 | Frame Shift Del (DEL) | VAF 21/159 reads (13%) | catalogued as rs1461294151; called by mutect2, pindel, varscan2
- CPSF7 | c.1162C>T p.R388C (on ENST00000394888 / NM_001136040.4; = p.R431C on NM_024811.4) | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV61212377; called by muse, mutect2
- CRPPA | c.322A>G p.I108V | Missense Mutation (SNP) | VAF 38/252 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as rs773043069; called by muse, mutect2, varscan2
- CRYBG2 | c.4261G>A p.A1421T | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV57488206; called by muse, mutect2, varscan2
- CSF1R | c.445A>G p.M149V | Missense Mutation (SNP) | VAF 60/530 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV53845115; called by muse, mutect2, varscan2
- CTNND2 | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1490647469, COSV58864690; called by muse, mutect2, varscan2
- CTSA | c.601-4A>G | Splice Region (SNP) | VAF 48/392 reads (12%) | catalogued as rs750972094; called by muse, varscan2
- CTSZ | c.118dup p.D40Gfs*16 | Frame Shift Ins (INS) | VAF 24/102 reads (24%) | catalogued as rs1441750300; called by mutect2, pindel, varscan2
- CUL9 | c.3813G>A p.W1271* | Nonsense Mutation (SNP) | VAF 36/456 reads (8%) | catalogued as COSV99335492; called by muse, mutect2
- CYB5R3 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs370243632; called by muse, mutect2
- CYP3A4 | c.140del p.L47Wfs*43 | Frame Shift Del (DEL) | VAF 21/203 reads (10%) | catalogued as rs1036437989; called by mutect2, pindel, varscan2
- DCAF12L1 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 17/225 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100948121; called by muse, mutect2
- DCHS1 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs765079321, COSV55043806; called by muse, mutect2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 11/95 reads (12%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX49 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 88/274 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763850904, COSV55355227; called by muse, mutect2, varscan2
- DDX5 | c.860G>A p.R287K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.203); catalogued as COSV56751420; called by muse, varscan2
- DHX30 | c.3517G>A p.A1173T (on ENST00000445061 / NM_138615.3; = p.A1134T on NM_014966.3) | Missense Mutation (SNP) | VAF 78/269 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as rs1174769783; called by muse, mutect2, varscan2
- DIP2C | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 57/286 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as rs755658110, COSV55169417, COSV99792160; called by muse, mutect2, varscan2
- DISC1 | c.2202del p.R735Gfs*12 | Frame Shift Del (DEL) | VAF 42/476 reads (9%) | catalogued as COSV100790088; called by mutect2, pindel
- DISP3 | c.2131G>A p.V711M | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.149); catalogued as rs770399056, COSV53837324; called by muse, mutect2, varscan2
- DLGAP1 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs749640273, COSV59812349; called by muse, mutect2, varscan2
- DNAH6 | c.1267A>G p.T423A | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV52880383; called by muse, mutect2
- DNAJC16 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777085250; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.48del p.D17Ifs*3 | Frame Shift Del (DEL) | VAF 20/84 reads (24%) | catalogued as rs1210343017; called by mutect2, pindel, varscan2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 34/126 reads (27%) | catalogued as rs772082432; called by mutect2, varscan2
- DYNC1LI1 | c.1288del p.I430Lfs*5 | Frame Shift Del (DEL) | VAF 18/135 reads (13%) | catalogued as rs748891796; called by mutect2, varscan2
- DZIP3 | c.1792+1G>A p.X598_splice | Splice Site (SNP) | VAF 5/33 reads (15%) | catalogued as rs142229557; called by mutect2, varscan2
- EDARADD | c.325del p.A109Pfs*4 (on ENST00000334232 / NM_145861.4; = p.A99Pfs*4 on NM_080738.4) | Frame Shift Del (DEL) | VAF 63/331 reads (19%) | catalogued as COSV62065812; called by mutect2, pindel, varscan2
- EP400 | c.6836G>A p.R2279Q | Missense Mutation (SNP) | VAF 98/280 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1322798961, COSV57775747; called by muse, mutect2, varscan2
- ERI3 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as rs1254143723; called by muse, mutect2, varscan2
- ESCO2 | c.1238G>T p.R413M | Missense Mutation (SNP) | VAF 70/295 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1470170491; called by muse, mutect2, varscan2
- EVPL | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.549); catalogued as rs1225213871, COSV56908760; called by muse, mutect2, varscan2
- EXOC3L4 | c.1771C>T p.R591W | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs902489139; called by muse, mutect2, varscan2
- EXOC6 | c.2407C>T p.H803Y | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1256260310; called by muse, mutect2, varscan2
- EZHIP | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1557318879, COSV100539415; called by muse, mutect2, varscan2
- F13B | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 52/356 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs780257236, COSV66372851; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F2 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.602); catalogued as rs199558597, COSV61315325, COSV61317795; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM133A | c.193dup p.M65Nfs*3 | Frame Shift Ins (INS) | VAF 18/81 reads (22%) | catalogued as rs760026337; called by mutect2, pindel, varscan2
- FAM91A1 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs760648737, COSV58235570; called by muse, mutect2, varscan2
- FAN1 | c.34del p.R12Gfs*45 | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | catalogued as rs752820596; called by mutect2, pindel, varscan2
- FH | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 121/622 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as rs778578307, COSV63817649; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FIZ1 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.251); catalogued as rs1325735883; called by muse, mutect2
- FNIP1 | c.3377G>T p.R1126M | Missense Mutation (SNP) | VAF 65/278 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV57198345; called by muse, mutect2, varscan2
- FOXD4 | c.385G>A p.G129S | Missense Mutation (SNP) | VAF 142/965 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs765820951; called by mutect2, varscan2
- FRAS1 | c.6434G>A p.R2145Q | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs201223320, COSV53596165; called by muse, mutect2
- FSIP2 | c.15523G>A p.A5175T | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.691); catalogued as rs1248533854; called by muse, mutect2
- FSTL5 | c.1799A>C p.D600A | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV60238022; called by muse, mutect2
- FUT10 | c.929G>A p.S310N | Missense Mutation (SNP) | VAF 23/231 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV59451710; called by muse, mutect2
- FZD7 | c.1426G>A p.V476M | Missense Mutation (SNP) | VAF 127/463 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV53810127; called by muse, mutect2, varscan2
- GABBR1 | c.2378G>A p.S793N | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.556); catalogued as rs1418330989; called by muse, varscan2
- GABRG1 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs778320362; called by muse, varscan2
- GAS2L2 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs373436768; called by muse, mutect2
- GATA4 | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 67/549 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs138404762, COSV58735119; called by muse, mutect2, varscan2
- GBE1 | c.314-3del | Splice Region (DEL) | VAF 10/46 reads (22%) | catalogued as rs1197398065; called by mutect2, pindel
- GJA8 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.053); catalogued as rs782314953, COSV53787681; called by muse, mutect2
- GLIS2 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 36/582 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1166186020; called by muse, mutect2
- GNPDA1 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747873200, COSV60942468; called by muse, mutect2, varscan2
- GPC6 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 52/294 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as rs200646263; called by muse, varscan2
- GPN1 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs773320443; called by muse, mutect2, varscan2
- GRIK3 | c.2269G>A p.G757R | Missense Mutation (SNP) | VAF 63/209 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770933463, COSV100902469; called by muse, mutect2, varscan2
- GRIN2A | c.4014del p.S1341Afs*56 | Frame Shift Del (DEL) | VAF 87/280 reads (31%) | catalogued as rs761213659, COSV58030294; called by mutect2, pindel, varscan2
- GRIN3A | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs541369716; called by muse, mutect2, varscan2
- GRK2 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 43/309 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261156029; called by muse, mutect2, varscan2
- GYG1 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 77/297 reads (26%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.769); catalogued as rs567555713; called by muse, mutect2, varscan2
- H1-5 | c.506del p.K169Rfs*? | Frame Shift Del (DEL) | VAF 40/246 reads (16%) | catalogued as COSV58899981; called by mutect2, pindel, varscan2
- HCFC1R1 | c.249del p.M84* | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | catalogued as rs746547303; called by mutect2, pindel, varscan2
- HDC | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 96/628 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370153946, COSV99984205; called by muse, mutect2, varscan2
- HDLBP | c.2057T>G p.V686G | Missense Mutation (SNP) | VAF 69/593 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs757259747; called by muse, mutect2, varscan2
- HECA | c.1004dup p.H336Tfs*25 | Frame Shift Ins (INS) | VAF 44/144 reads (31%) | catalogued as rs771658394; called by mutect2, varscan2
- HELZ2 | c.2353G>A p.V785M (on ENST00000467148 / NM_001037335.2; = p.V216M on NM_033405.3) | Missense Mutation (SNP) | VAF 63/232 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1292221232; called by muse, mutect2, varscan2
- HGFAC | c.1745T>G p.L582R | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138538142; called by muse, mutect2, varscan2
- HIF1A | c.112del p.Y38Mfs*13 | Frame Shift Del (DEL) | VAF 52/152 reads (34%) | catalogued as rs760088435; called by mutect2, varscan2
- HK3 | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs780844872; called by muse, mutect2, varscan2
- HKDC1 | c.2320C>T p.R774C | Missense Mutation (SNP) | VAF 64/292 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.047); catalogued as rs537386563, COSV63579347; called by muse, mutect2, varscan2
- HMGCS1 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 50/433 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs780589640, COSV57290279; called by muse, mutect2, varscan2
- HNF1A | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 73/494 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as CM082865; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1283G>A p.G428D | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54565765, COSV54567632; called by muse, mutect2, varscan2
- HOXA13 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.9); PolyPhen benign (0.024); catalogued as COSV56083500; called by muse, mutect2, varscan2
- HS3ST4 | c.632G>C p.R211P | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58831345; called by muse, mutect2
- HTR5A | c.356C>A p.A119E | Missense Mutation (SNP) | VAF 71/182 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV55283775; called by muse, mutect2, varscan2
- HVCN1 | c.256del p.D87Tfs*6 | Frame Shift Del (DEL) | VAF 10/121 reads (8%) | catalogued as rs775475972; called by mutect2, pindel
- IGLC7 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 205/913 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.245); catalogued as rs373960869; called by muse, mutect2, varscan2
- IGSF9 | c.1345G>A p.V449I (on ENST00000368094 / NM_001135050.2; = p.V433I on NM_020789.4) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs147852722; called by muse, mutect2, varscan2
- IL17RE | c.644T>C p.L215P | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as rs1230742813; called by muse, mutect2, varscan2
- INPP5E | c.256C>A p.L86M | Missense Mutation (SNP) | VAF 48/211 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51529730; called by muse, mutect2, varscan2
- INSRR | c.3802del p.A1268Pfs*110 | Frame Shift Del (DEL) | VAF 109/975 reads (11%) | catalogued as COSV100947553; called by mutect2, pindel
- IPO13 | c.2720C>T p.A907V | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs758616316; called by muse, mutect2, varscan2
- IPPK | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 36/362 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.118); catalogued as rs777372135; called by muse, mutect2, varscan2
- IQCE | c.1616del p.K539Rfs*25 | Frame Shift Del (DEL) | VAF 22/88 reads (25%) | catalogued as rs759821884; called by mutect2, varscan2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 4/11 reads (36%) | catalogued as rs761880048; called by mutect2, varscan2
- ITPRID1 | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750560323, COSV60072418; called by muse, mutect2, varscan2
- JMJD4 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as rs761894520; called by muse, mutect2, varscan2
- KCNC3 | c.1742del p.P581Rfs*27 | Frame Shift Del (DEL) | VAF 77/297 reads (26%) | catalogued as COSV65387095; called by mutect2, pindel, varscan2
- KCNG2 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.057); catalogued as rs748713635, COSV60270617; called by muse, varscan2
- KCNJ10 | c.62T>C p.M21T | Missense Mutation (SNP) | VAF 122/716 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs878854483; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNJ3 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 28/562 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54535418; called by muse, mutect2
- KCNK1 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 20/413 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.247); catalogued as rs1400981676, COSV64035238; called by muse, mutect2
- KIAA2026 | c.2278G>A p.V760I | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.067); catalogued as rs1563906690; called by muse, mutect2, varscan2
- KIF26B | c.2842G>A p.E948K | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as rs766437205, COSV63638738; called by muse, mutect2, varscan2
- KLF4 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 51/316 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs760546357; called by muse, mutect2, varscan2
- KLHL30 | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.075); catalogued as COSV59978424; called by muse, mutect2
- KLHL42 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 89/340 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as rs560966730; called by muse, mutect2, varscan2
- KRT17 | c.65del p.G22Afs*93 | Frame Shift Del (DEL) | VAF 68/243 reads (28%) | catalogued as rs753167272; called by mutect2, pindel, varscan2
- LAMA1 | c.2700C>T p.R900= | Splice Region (SNP) | VAF 26/209 reads (12%) | catalogued as rs140067215; called by muse, mutect2
- LEF1 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 68/221 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as rs200236123; called by muse, mutect2, varscan2
- LGSN | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as rs139295115; called by muse, mutect2, varscan2
- LIPC | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 139/471 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs369706830; called by muse, mutect2, varscan2
- LIPT2 | c.530C>T p.T177M | Missense Mutation (SNP) | VAF 93/404 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.238); catalogued as COSV100030867; called by muse, mutect2, varscan2
- LMAN1 | c.823-2del p.X275_splice | Splice Site (DEL) | VAF 16/129 reads (12%) | catalogued as rs765287063; called by mutect2, varscan2
- LRRTM3 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 26/278 reads (9%) | catalogued as COSV63664927; called by muse, mutect2
- LYZL4 | c.291C>T p.S97= | Splice Region (SNP) | VAF 46/144 reads (32%) | catalogued as rs752462879, COSV55104783; called by muse, mutect2
- MAP2K7 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 59/215 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101209051, COSV67609125; called by muse, mutect2, varscan2
- MAP4 | c.2755del p.R919Gfs*14 | Frame Shift Del (DEL) | VAF 35/126 reads (28%) | catalogued as rs778275488, COSV53142223; called by mutect2, pindel, varscan2
- MATK | c.1067G>A p.R356H (on ENST00000310132 / NM_139355.3; = p.R357H on NM_002378.4) | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59554696; called by muse, mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 51/138 reads (37%) | catalogued as rs780635289; called by mutect2, varscan2
- MGAM | c.4513G>T p.G1505W | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72074484; called by muse, mutect2
- MKLN1 | c.1672T>C p.W558R | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1407530920; called by muse, mutect2, varscan2
- MPP2 | c.376-3del | Splice Region (DEL) | VAF 22/91 reads (24%) | catalogued as rs769731446; called by mutect2, pindel, varscan2
- MYO5C | c.2039G>A p.R680H | Missense Mutation (SNP) | VAF 22/279 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs1034890137, COSV99954470; called by muse, mutect2
- MYOD1 | c.650dup p.S218Efs*60 | Frame Shift Ins (INS) | VAF 29/134 reads (22%) | catalogued as rs781603622; called by mutect2, pindel, varscan2
- MYPOP | c.1139del p.P380Hfs*26 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | catalogued as rs757587344; called by mutect2, pindel
- NAA30 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs1399850982, COSV53649606; called by muse, mutect2, varscan2
- NBEAL2 | c.1915G>A p.G639S | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368413492; called by muse, mutect2, varscan2
- NBR1 | c.2236del p.L746Wfs*50 | Frame Shift Del (DEL) | VAF 48/331 reads (15%) | catalogued as rs34660735; called by mutect2, pindel, varscan2
- NCAM1 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 109/386 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.151); catalogued as COSV57515835; called by muse, mutect2, varscan2
- NFAM1 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs372030282; called by muse, mutect2, varscan2
- NFATC1 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 100/392 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as rs1218389113; called by muse, mutect2, varscan2
- NFRKB | c.65G>A p.G22D (on ENST00000446488 / NM_001143835.2; = p.G35D on NM_006165.3) | Missense Mutation (SNP) | VAF 31/320 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV58760412; called by muse, mutect2, varscan2
- NID1 | c.2336A>G p.Y779C | Missense Mutation (SNP) | VAF 50/540 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as rs1474818232; called by muse, mutect2
- NINJ1 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs144669023; called by muse, mutect2, varscan2
- NOM1 | c.626T>C p.L209P | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.36); catalogued as rs1373086079; called by muse, mutect2, varscan2
- NPR1 | c.2399C>T p.T800M | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as rs757509380, COSV64118055; called by muse, mutect2, varscan2
- NSD3 | c.1311G>T p.E437D | Missense Mutation (SNP) | VAF 48/403 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV57620023; called by muse, mutect2, varscan2
- NUMA1 | c.5068G>A p.A1690T | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59643391; called by muse, mutect2, varscan2
- OAS3 | c.2041C>A p.P681T | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as rs1274826561; called by muse, mutect2
- OBSCN | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 112/572 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV52814031; called by muse, mutect2, varscan2
- OR11L1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 68/369 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs536790643, COSV63313548; called by muse, mutect2, varscan2
- OR13C3 | c.479T>C p.L160P | Missense Mutation (SNP) | VAF 82/264 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765748459; called by muse, mutect2, varscan2
- OSBPL2 | c.492G>A p.R164= (on ENST00000313733 / NM_144498.4; = p.R152= on NM_014835.4) | Splice Region (SNP) | VAF 26/81 reads (32%) | catalogued as rs267606042; called by muse, varscan2
- OXCT2 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs754360890, COSV59593787; called by mutect2, varscan2
- P3H2 | c.1444G>A p.V482M | Missense Mutation (SNP) | VAF 38/468 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.282); catalogued as rs754396355; called by muse, mutect2
- PARP10 | c.2534G>A p.R845H | Missense Mutation (SNP) | VAF 8/165 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs537594359; called by muse, mutect2
- PBX2 | c.1190G>T p.R397L | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as COSV100904009; called by muse, varscan2
- PCDHA5 | c.2162G>A p.R721Q | Missense Mutation (SNP) | VAF 84/293 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.889); catalogued as rs868968697, COSV100972455; called by muse, mutect2, varscan2
- PCDHB7 | c.976G>A p.G326R | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1554280062; called by muse, mutect2, varscan2
- PCDHGA4 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 80/221 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as COSV99532129; called by muse, mutect2, varscan2
- PCNT | c.7691-2A>G p.X2564_splice | Splice Site (SNP) | VAF 56/172 reads (33%) | catalogued as rs1257586179; called by muse, mutect2, varscan2
- PFKFB3 | c.496A>G p.M166V | Missense Mutation (SNP) | VAF 60/300 reads (20%) | PolyPhen benign (0); catalogued as rs1039167609; called by muse, mutect2, varscan2
- PGAM4 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 139/435 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.218); catalogued as rs376675574, COSV100431030; called by muse, mutect2, varscan2
- PGBD1 | c.2275T>C p.Y759H | Missense Mutation (SNP) | VAF 92/235 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV52552283; called by muse, mutect2, varscan2
- PGGT1B | c.338C>T p.T113I | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1321763781; called by muse, mutect2, varscan2
- PHLDB1 | c.2650_2652del p.K884del | In Frame Del (DEL) | VAF 47/207 reads (23%) | catalogued as rs782112381; called by mutect2, pindel, varscan2
- PHOSPHO1 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as rs1293407795, COSV99865802; called by muse, mutect2, varscan2
- PI4KA | c.5965G>A p.G1989S | Missense Mutation (SNP) | VAF 54/418 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs771895517; called by mutect2, varscan2
- PJA1 | c.1028G>A p.R343H (on ENST00000361478 / NM_145119.4; = p.R155H on NM_022368.5) | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.379); catalogued as rs140630019, COSV100824619, COSV64053358; called by muse, mutect2, varscan2
- PKD1 | c.2420C>T p.S807F | Missense Mutation (SNP) | VAF 189/653 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs1222764731, COSV51927768; called by muse, mutect2, varscan2
- PKHD1L1 | c.10366G>A p.A3456T | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs1006342700, COSV65754444; called by muse, mutect2
- PLEKHM1 | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 36/480 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1414621264; called by muse, mutect2
- PLEKHN1 | c.707G>A p.R236Q (on ENST00000379409; = p.R196Q on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs745703099, COSV58020938; called by muse, mutect2, varscan2
- PLXNA3 | c.3275G>A p.R1092Q | Missense Mutation (SNP) | VAF 97/344 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs782513504, COSV63754636, COSV63755502; called by muse, mutect2, varscan2
- PMEPA1 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 38/256 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1369377992; called by muse, varscan2
- POM121C | c.3562G>A p.A1188T (on ENST00000607367; = p.A946T on NM_001099415.3) | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0.01); catalogued as rs782172556; called by muse, mutect2, varscan2
- PPIE | c.912del p.S306Afs*35 | Frame Shift Del (DEL) | VAF 25/117 reads (21%) | catalogued as rs755183076; called by mutect2, pindel, varscan2
- PPP6R1 | c.157del p.H53Tfs*33 | Frame Shift Del (DEL) | VAF 36/139 reads (26%) | catalogued as COSV69800555; called by mutect2, pindel, varscan2
- PPRC1 | c.2819del p.P940Hfs*6 | Frame Shift Del (DEL) | VAF 44/189 reads (23%) | catalogued as rs768056539; called by mutect2, varscan2
- PRAMEF1 | c.934T>C p.C312R | Missense Mutation (SNP) | VAF 90/368 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs754597619; called by muse, mutect2, varscan2
- PRG2 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0.011); catalogued as rs375145993; called by muse, mutect2, varscan2
- PRKACG | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 30/233 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs1167402842, COSV55240604; called by muse, mutect2, varscan2
- PROS1 | c.1242del p.F414Lfs*33 | Frame Shift Del (DEL) | VAF 50/194 reads (26%) | catalogued as CD066393, CX013892; called by mutect2, pindel, varscan2
- PRPF18 | c.181T>C p.S61P | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as rs765706484; called by muse, mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 20/162 reads (12%) | catalogued as rs753236928; called by mutect2, varscan2
- PRR35 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as rs758647792, COSV53464836; called by muse, mutect2, varscan2
- PRRC2A | c.332T>C p.L111P | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV63224983; called by muse, mutect2, varscan2
- PSD3 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); catalogued as rs189891634, COSV58965108; called by muse, mutect2, varscan2
- PTCHD4 | c.1405A>G p.I469V | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.461); catalogued as COSV100259918; called by muse, mutect2, varscan2
- PTP4A3 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs371648082; called by muse, mutect2, varscan2
- PTPRC | c.3373T>C p.W1125R | Missense Mutation (SNP) | VAF 49/307 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1455290898, COSV61418349; called by muse, mutect2, varscan2
- PTX4 | c.521G>A p.R174Q (on ENST00000447419 / NM_001328608.2; = p.R169Q on NM_001013658.1) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746126250; called by muse, mutect2, varscan2
- PUM1 | c.2365C>G p.P789A | Missense Mutation (SNP) | VAF 66/235 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV57085272; called by muse, mutect2, varscan2
- PXYLP1 | c.371C>A p.P124Q | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99649683; called by muse, mutect2, varscan2
- RAI14 | c.2926C>T p.Q976* | Nonsense Mutation (SNP) | VAF 12/180 reads (7%) | catalogued as rs1160113246; called by muse, mutect2
- RASGRF1 | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs372905205, COSV69176911; called by muse, mutect2, varscan2
- RBAK-RBAKDN | c.394C>T p.R132W (on ENST00000407184; = p.P111= on NM_001204513.3) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1010396669; called by muse, mutect2
- RBCK1 | c.1090C>T p.R364C (on ENST00000356286 / NM_031229.4; = p.R322C on NM_006462.6) | Missense Mutation (SNP) | VAF 69/224 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs144018482, COSV100675887; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBM14 | c.1792A>G p.M598V | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs1182576493; called by muse, mutect2, varscan2
- RBM43 | c.406del p.I136Sfs*4 | Frame Shift Del (DEL) | VAF 52/207 reads (25%) | catalogued as rs142934811, CD1212851; called by mutect2, varscan2
- RBM6 | c.1840C>T p.R614C | Missense Mutation (SNP) | VAF 50/532 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs746467806; called by muse, mutect2
- RELN | c.-5_1dup p.P1_?0 | Translation Start Site (INS) | VAF 11/76 reads (14%) | catalogued as rs1554453538; called by mutect2, pindel
- REM1 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 61/220 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs749761528, COSV52429909; called by muse, mutect2, varscan2
- REPS1 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as rs753423217, COSV57808905; called by muse, mutect2, varscan2
- REST | c.2087C>T p.T696M | Missense Mutation (SNP) | VAF 129/383 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs780817845, COSV58359330, COSV58361976; called by muse, mutect2, varscan2
- REV1 | c.2767C>T p.Q923* | Nonsense Mutation (SNP) | VAF 43/132 reads (33%) | catalogued as rs761339709, COSV51484160; called by muse, mutect2, varscan2
- RFT1 | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 33/262 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.053); catalogued as rs764531159; called by muse, mutect2, varscan2
- RFXAP | c.359del p.G120Afs*18 | Frame Shift Del (DEL) | VAF 14/165 reads (8%) | catalogued as rs1224857205; called by mutect2, pindel
- RHD | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 126/407 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.019); catalogued as rs530929152, CM076460, COSV100155054; called by muse, mutect2, varscan2
- RIN1 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs141887009; called by muse, mutect2, varscan2
- RIN3 | c.575A>G p.K192R | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.023); catalogued as rs751948238; called by muse, mutect2
- RNF175 | c.544G>T p.V182L | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56844406; called by muse, mutect2
- RPS6KL1 | c.545G>A p.C182Y | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV63581922; called by muse, mutect2
- SASH1 | c.3071G>A p.G1024D | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV66564817; called by muse, mutect2
- SCAF4 | c.3007_3009del p.R1003del | In Frame Del (DEL) | VAF 67/326 reads (21%) | catalogued as rs762039419; called by pindel, varscan2
- SCAP | c.782G>A p.S261N | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.889); catalogued as rs1423480827, COSV55566798; called by muse, mutect2, varscan2
- SCG5 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 138/485 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs756980769; called by muse, mutect2, varscan2
- SCN1A | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 37/358 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.34); catalogued as rs1437209028, COSV57688842; called by muse, mutect2
- SCUBE3 | c.286A>G p.T96A | Missense Mutation (SNP) | VAF 24/247 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs748538268; called by muse, mutect2, varscan2
- SDAD1 | c.824del p.K275Rfs*15 | Frame Shift Del (DEL) | VAF 11/83 reads (13%) | catalogued as rs763181092; called by mutect2, pindel, varscan2
- SEBOX | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 12/87 reads (14%) | catalogued as rs1555582679; called by muse, mutect2, varscan2
- SEC24C | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs554903997; called by muse, mutect2, varscan2
- SEL1L2 | c.1483A>G p.I495V | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1211195627; called by muse, mutect2, varscan2
- SEMA3G | c.1591G>T p.E531* | Nonsense Mutation (SNP) | VAF 48/666 reads (7%) | catalogued as COSV99203549; called by muse, mutect2
- SERINC2 | c.783C>T p.D261= (on ENST00000373709 / NM_178865.5; = p.D265= on NM_018565.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 18/143 reads (13%) | catalogued as rs558799797, COSV65490899; called by muse, mutect2, varscan2
- SESN2 | c.1212-2A>G p.X404_splice | Splice Site (SNP) | VAF 18/130 reads (14%) | catalogued as rs766127829; called by muse, mutect2
- SETD2 | c.5383A>G p.K1795E | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV57450438; called by muse, mutect2, varscan2
- SETDB1 | c.3220C>T p.R1074C | Missense Mutation (SNP) | VAF 52/320 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.667); catalogued as rs147846533; called by muse, mutect2, varscan2
- SFR1 | c.378A>T p.E126D (on ENST00000369727 / NM_001002759.1; = p.E113D on NM_145247.4) | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV60479630; called by muse, mutect2, varscan2
- SHANK1 | c.1450G>A p.G484R | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs778834894, COSV53250577; called by muse, mutect2, varscan2
- SHISA7 | c.1076del p.G359Afs*178 | Frame Shift Del (DEL) | VAF 11/104 reads (11%) | catalogued as rs1568449946; called by mutect2, pindel, varscan2
- SLAMF1 | c.829del p.S277Afs*54 | Frame Shift Del (DEL) | VAF 66/310 reads (21%) | catalogued as rs751442558; called by mutect2, varscan2
- SLC12A4 | c.2792A>G p.Q931R | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs1478809403; called by muse, mutect2
- SLC17A3 | c.940G>A p.G314S | Missense Mutation (SNP) | VAF 63/529 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371645741; called by muse, mutect2, varscan2
- SLC18A3 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV60319635; called by muse, mutect2, varscan2
- SLC1A2 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs147645566; called by muse, mutect2, varscan2
- SLC22A12 | c.511G>T p.G171W | Missense Mutation (SNP) | VAF 139/542 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1565134068; called by muse, mutect2, varscan2
- SLC25A18 | c.367A>G p.M123V | Missense Mutation (SNP) | VAF 63/252 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs893707906; called by muse, mutect2, varscan2
- SLC38A7 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs938062870; called by muse, mutect2
- SLC45A4 | c.2399T>A p.I800N (on ENST00000517878 / NM_001286646.2; = p.F747I on NM_001080431.2) | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1248963620, COSV50186823; called by muse, mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs759883814, COSV56092392; called by mutect2, varscan2
- SLC9A2 | c.2173del p.Q725Sfs*11 | Frame Shift Del (DEL) | VAF 48/233 reads (21%) | catalogued as rs864309496, COSV52138587; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- SLC9A9 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 71/281 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57225941; called by muse, mutect2, varscan2
- SLF2 | c.2360del p.L787* | Frame Shift Del (DEL) | VAF 32/161 reads (20%) | catalogued as rs1007972651, COSV53275602; called by mutect2, pindel, varscan2
- SMARCAD1 | c.1040del p.N347Mfs*24 | Frame Shift Del (DEL) | VAF 22/84 reads (26%) | catalogued as rs754697669; called by mutect2, varscan2
- SMR3A | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0); catalogued as rs767937697; called by muse, mutect2, varscan2
- SP110 | c.1930T>C p.F644L | Missense Mutation (SNP) | VAF 163/584 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs1206478104; called by muse, mutect2, varscan2
- SPIRE2 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1420371808; called by muse, mutect2, varscan2
- SPRED3 | c.1102G>C p.A368P | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.829); catalogued as COSV58312688; called by muse, mutect2, varscan2
- SRCIN1 | c.1107del p.R370Afs*39 (on ENST00000621492; = p.R336Afs*39 on NM_025248.3) | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | catalogued as rs1567865483; called by pindel, varscan2
- SSC5D | c.1904del p.N635Mfs*11 | Frame Shift Del (DEL) | VAF 55/370 reads (15%) | catalogued as COSV67476706; called by mutect2, pindel, varscan2
- ST14 | c.2392G>A p.V798M | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs531412139; called by muse, mutect2
- STAB1 | c.7052G>A p.R2351Q | Missense Mutation (SNP) | VAF 69/257 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.127); catalogued as rs150314414; called by muse, mutect2, varscan2
- STARD13 | c.802G>A p.G268R (on ENST00000336934 / NM_001243476.3; = p.G150R on NM_052851.3) | Missense Mutation (SNP) | VAF 107/300 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs769512023; called by muse, mutect2, varscan2
- STK10 | c.2413C>T p.R805W | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756323576, COSV51572678; called by muse, mutect2, varscan2
- SUCLG2 | c.1316del p.L439Yfs*8 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs757697438; called by mutect2, varscan2
- SUPT6H | c.4318C>T p.R1440C | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs763471052, COSV58930877; called by muse, mutect2, varscan2
- TAS2R10 | c.587del p.L196* | Frame Shift Del (DEL) | VAF 54/219 reads (25%) | catalogued as rs1406115943; called by mutect2, pindel, varscan2
- TASOR | c.4616G>A p.S1539N (on ENST00000355628 / NM_001365636.2; = p.S1163N on NM_015224.3) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1393963282; called by muse, mutect2, varscan2
- TBC1D16 | c.2152G>A p.G718S | Missense Mutation (SNP) | VAF 57/208 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs942640132; called by muse, mutect2, varscan2
- TBC1D17 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs748913091, COSV55579673; called by muse, mutect2, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 54/185 reads (29%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- TBXA2R | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 82/778 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1268055705; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 28/123 reads (23%) | catalogued as rs763321097; called by mutect2, varscan2
- TELO2 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 55/311 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs775091661; called by muse, mutect2, varscan2
- TERT | c.1918G>A p.V640M | Missense Mutation (SNP) | VAF 72/511 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as rs765195721, COSV57205828; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TEX30 | c.89A>G p.Y30C | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as rs772701933, COSV101052045; called by muse, mutect2, varscan2
- TFB2M | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.667); catalogued as rs754216735, COSV63624761; called by muse, mutect2, varscan2
- TLN2 | c.214T>A p.Y72N | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60891360; called by muse, mutect2
- TMCC3 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs762276134; called by muse, mutect2, varscan2
- TMEM106B | c.344del p.F115Sfs*9 | Frame Shift Del (DEL) | VAF 16/192 reads (8%) | catalogued as COSV67544212; called by mutect2, pindel
- TMEM151B | c.305T>C p.M102T | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs552359207; called by muse, mutect2, varscan2
- TMEM178B | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 58/216 reads (27%) | catalogued as COSV73743934; called by muse, mutect2, varscan2
- TMEM202 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 26/374 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs199872123; called by muse, mutect2
- TMEM255B | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.868); catalogued as rs768753433, COSV64713225; called by muse, mutect2, varscan2
- TMEM41A | c.467del p.F156Sfs*5 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as rs758476632; called by mutect2, varscan2
- TMEM8B | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 17/326 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV65076659; called by muse, mutect2
- TMPRSS7 | c.413G>A p.R138Q (on ENST00000452346; = p.R26Q on NM_001042575.2) | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1049072963; called by muse, mutect2, varscan2
- TOM1L2 | c.128C>T p.T43M | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771164302, COSV58885085; called by muse, mutect2, varscan2
- TP73 | c.1307del p.P436Rfs*31 | Frame Shift Del (DEL) | VAF 21/110 reads (19%) | catalogued as COSV60701701; called by mutect2, pindel, varscan2
- TPTE | c.839G>A p.R280Q (on ENST00000618007 / NM_199261.4; = p.R262Q on NM_199259.4) | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT tolerated (0.84); PolyPhen benign (0.069); catalogued as rs532485045; called by muse, mutect2
- TPTE | c.1268C>T p.S423L (on ENST00000618007 / NM_199261.4; = p.S405L on NM_199259.4) | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as rs570468666; called by muse, varscan2
- TRAPPC9 | c.1958C>T p.T653M | Missense Mutation (SNP) | VAF 48/671 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs190087909; called by muse, mutect2
- TRAV12-3 | c.226G>T p.G76C | Missense Mutation (SNP) | VAF 34/296 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1414028185; called by muse, mutect2, varscan2
- TRIM44 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1224201368; called by muse, mutect2, varscan2
- TSPAN6 | c.305del p.L102Wfs*9 | Frame Shift Del (DEL) | VAF 68/210 reads (32%) | catalogued as rs757907711; called by mutect2, varscan2
- TTBK1 | c.1316dup p.D440Rfs*19 | Frame Shift Ins (INS) | VAF 22/78 reads (28%) | catalogued as rs757606010; called by mutect2, varscan2
- TTC24 | c.1187C>A p.A396D | Missense Mutation (SNP) | VAF 46/305 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.839); catalogued as COSV63998204; called by muse, mutect2, varscan2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs756650873; called by mutect2, varscan2
- TTC3 | c.4692del p.E1565Kfs*6 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as rs778730652; called by mutect2, varscan2
- TXLNG | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 73/272 reads (27%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs1486780340; called by muse, mutect2, varscan2
- VARS2 | c.2536G>A p.A846T | Missense Mutation (SNP) | VAF 59/213 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.5); catalogued as rs761767299; called by muse, mutect2, varscan2
- VRK3 | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199516963, COSV57464948; called by muse, mutect2, varscan2
- WAC | c.443A>G p.Y148C | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1564404246; called by muse, mutect2
- WAS | c.584T>C p.L195P | Missense Mutation (SNP) | VAF 18/221 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.274); catalogued as COSV64996982; called by muse, mutect2
- WASF3 | c.920del p.P307Rfs*28 | Frame Shift Del (DEL) | VAF 74/142 reads (52%) | catalogued as rs756173793; called by mutect2, varscan2
- WBP1 | c.552del p.H185Ifs*10 | Frame Shift Del (DEL) | VAF 60/228 reads (26%) | catalogued as rs773064295, COSV51967888; called by mutect2, varscan2
- WBP11 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV53762290; called by muse, mutect2
- WWC1 | c.2878C>T p.R960* | Nonsense Mutation (SNP) | VAF 31/244 reads (13%) | catalogued as rs1016369196, COSV54650280; called by muse, mutect2, varscan2
- XAB2 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 72/273 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as rs199640570, COSV60696862, COSV60698284; called by muse, mutect2, varscan2
- XRCC5 | c.858del p.E287Kfs*11 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | catalogued as rs1559240395; called by mutect2, pindel, varscan2
- Z83844.2 | c.987del p.E330Rfs*9 | Frame Shift Del (DEL) | VAF 18/140 reads (13%) | catalogued as rs1569008643; called by mutect2, pindel, varscan2
- ZFHX3 | c.10215del p.A3407Lfs*78 | Frame Shift Del (DEL) | VAF 26/99 reads (26%) | catalogued as rs762108866; called by mutect2, pindel, varscan2
- ZKSCAN4 | c.1624dup p.T542Nfs*21 | Frame Shift Ins (INS) | VAF 38/116 reads (33%) | catalogued as rs757603403; called by mutect2, varscan2
- ZNF233 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as rs1276801373; called by muse, mutect2, varscan2
- ZNF280C | c.554C>T p.T185I | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.405); catalogued as rs1432534149; called by muse, mutect2, varscan2
- ZNF317 | c.1075del p.E359Rfs*51 | Frame Shift Del (DEL) | VAF 72/273 reads (26%) | catalogued as COSV56109326; called by mutect2, pindel, varscan2
- ZNF518A | c.3320del p.L1107* | Frame Shift Del (DEL) | VAF 35/184 reads (19%) | catalogued as COSV100283456; called by mutect2, pindel, varscan2
- ZNF830 | c.753del p.F251Lfs*6 | Frame Shift Del (DEL) | VAF 38/220 reads (17%) | catalogued as rs749765261; called by mutect2, varscan2
- ZXDC | c.2186del p.K729Sfs*19 | Frame Shift Del (DEL) | VAF 73/271 reads (27%) | catalogued as rs1198185803, COSV60448663; called by mutect2, pindel, varscan2
- ABCA10 | c.93del p.K31Nfs*18 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | called by mutect2, pindel, varscan2
- ABCC12 | c.3131T>C p.V1044A | Missense Mutation (SNP) | VAF 21/344 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- AC005324.2 | c.827G>A p.S276N | Missense Mutation (SNP) | VAF 50/315 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- ACAP2 | c.1866G>A p.M622I | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ACSF2 | c.58del p.V20Cfs*81 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | called by mutect2, pindel, varscan2
- ACSL4 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ADAMTS13 | c.1319dup p.T441Dfs*93 | Frame Shift Ins (INS) | VAF 68/295 reads (23%) | called by pindel, varscan2
- ADAMTS6 | c.2014G>T p.G672W | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ADAMTS7 | c.1727A>G p.Y576C | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADAMTS9 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 43/412 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY4 | c.2868dup p.G957Wfs*13 | Frame Shift Ins (INS) | VAF 30/216 reads (14%) | called by mutect2, pindel, varscan2
- ADCYAP1 | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- ADGRB1 | c.2629A>G p.N877D | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- ADGRD1 | c.463A>T p.T155S | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.192); called by muse, varscan2
- ADGRL1 | c.4361C>T p.A1454V (on ENST00000340736 / NM_001008701.3; = p.A1449V on NM_014921.5) | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- ADGRL3 | c.1479A>G p.K493= (on ENST00000506720 / NM_001322402.2; = p.K425= on NM_015236.6) | Splice Region (SNP) | VAF 26/181 reads (14%) | called by muse, mutect2, varscan2
- ADRA1D | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AGAP6 | c.116G>T p.R39M | Missense Mutation (SNP) | VAF 76/434 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); called by muse, varscan2
- AGMAT | c.1041del p.V349* | Frame Shift Del (DEL) | VAF 76/279 reads (27%) | called by mutect2, pindel, varscan2
- AHCTF1 | c.2375C>T p.A792V (on ENST00000366508; = p.A766V on NM_015446.5) | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AKAP3 | c.1914del p.R639Gfs*15 | Frame Shift Del (DEL) | VAF 39/140 reads (28%) | called by mutect2, pindel, varscan2
- AKNA | c.3847G>A p.A1283T | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKH | c.85T>G p.F29V | Missense Mutation (SNP) | VAF 32/307 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ANKRD11 | c.3220A>T p.K1074* | Nonsense Mutation (SNP) | VAF 82/752 reads (11%) | called by muse, mutect2, varscan2
- ANKRD27 | c.1457G>A p.G486D | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD28 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ANO9 | c.1519C>T p.R507W | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANXA10 | c.176A>G p.Y59C | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APC2 | c.4245del p.R1416Gfs*164 | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | called by pindel, varscan2
- APOA4 | c.883C>T p.H295Y | Missense Mutation (SNP) | VAF 24/514 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.048); called by muse, mutect2
- APOC2 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 42/322 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- APOL6 | c.792G>T p.R264S | Missense Mutation (SNP) | VAF 103/364 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- APP | c.257T>C p.V86A | Missense Mutation (SNP) | VAF 41/376 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ARFGEF1 | c.3935A>G p.H1312R | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); called by muse, varscan2
- ARID1A | c.827del p.G276Efs*87 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by pindel, varscan2
- ARL14EPL | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 118/410 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARL6IP1 | c.127T>C p.W43R | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARNT | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 60/426 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATF2 | c.318del p.M107Cfs*3 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel
- ATG9B | c.2555dup p.E853* | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | called by mutect2, pindel, varscan2
- ATL3 | c.1270T>A p.L424I | Missense Mutation (SNP) | VAF 70/315 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ATP11B | c.520A>G p.T174A | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP6V0D1 | c.817-8del | Splice Region (DEL) | VAF 20/184 reads (11%) | called by mutect2, pindel
- ATP8A1 | c.1948-2A>G p.X650_splice | Splice Site (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2
- ATP8B1 | c.3307A>T p.I1103F | Missense Mutation (SNP) | VAF 69/226 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.369); called by mutect2, varscan2
- ATP8B3 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- AVIL | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 22/177 reads (12%) | called by muse, mutect2, varscan2
- B3GALT1 | c.800A>G p.Y267C | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- B3GNT4 | c.960G>A p.M320I | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- BAG6 | c.344del p.P115Lfs*53 | Frame Shift Del (DEL) | VAF 16/150 reads (11%) | called by mutect2, pindel
- BARD1 | c.313A>G p.I105V | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- BAZ2B | c.1616C>T p.T539I | Missense Mutation (SNP) | VAF 35/307 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- BCAM | c.41C>A p.P14Q | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- BCL2L2-PABPN1 | c.*5del | Frame Shift Del (DEL) | VAF 31/202 reads (15%) | called by mutect2, pindel, varscan2
- BCOR | c.1094C>A p.S365Y | Missense Mutation (SNP) | VAF 24/518 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2
- BEGAIN | c.553A>G p.K185E | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- BICD2 | c.1744T>G p.S582A | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BIN1 | c.1646T>C p.V549A (on ENST00000316724 / NM_001320642.1; = p.V410A on NM_004305.4) | Missense Mutation (SNP) | VAF 134/545 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRPF3 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BTBD8 | c.2680A>G p.K894E (on ENST00000636805 / NM_001376131.1; = p.K381E on NM_015237.4) | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- C11orf65 | c.632A>G p.K211R | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- C11orf94 | c.175+5T>C | Splice Region (SNP) | VAF 39/141 reads (28%) | called by muse, mutect2, varscan2
- C1QTNF4 | c.176del p.G59Afs*34 | Frame Shift Del (DEL) | VAF 71/228 reads (31%) | called by mutect2, pindel, varscan2
- C20orf96 | c.464C>A p.A155E (on ENST00000360321 / NM_153269.3; = p.A154E on NM_080571.1) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.015); called by muse, mutect2
- CACNG1 | c.368T>C p.L123P | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- CAMTA2 | c.2280+2T>C p.X760_splice | Splice Site (SNP) | VAF 43/252 reads (17%) | called by muse, varscan2
- CAPN2 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 32/374 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- CARMIL3 | c.2032C>T p.Q678* | Nonsense Mutation (SNP) | VAF 62/267 reads (23%) | called by muse, mutect2, varscan2
- CBLB | c.2896A>G p.I966V | Missense Mutation (SNP) | VAF 50/241 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CCDC141 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CCDC148 | c.1260del p.K420Nfs*15 | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | called by mutect2, pindel, varscan2
- CCDC163 | c.386C>A p.P129H | Missense Mutation (SNP) | VAF 35/387 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); called by muse, mutect2
- CCNI2 | c.775-7T>C | Splice Region (SNP) | VAF 29/255 reads (11%) | called by muse, mutect2, varscan2
- CD48 | c.588C>A p.C196* | Nonsense Mutation (SNP) | VAF 95/511 reads (19%) | called by muse, mutect2, varscan2
- CD82 | c.541dup p.E181Gfs*27 | Frame Shift Ins (INS) | VAF 106/361 reads (29%) | called by mutect2, pindel, varscan2
- CD83 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- CDC73 | c.11T>A p.V4E | Missense Mutation (SNP) | VAF 166/279 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- CDH4 | c.827A>C p.E276A | Missense Mutation (SNP) | VAF 29/301 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.319); called by muse, mutect2
- CDH5 | c.1933T>C p.Y645H | Missense Mutation (SNP) | VAF 20/231 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CELF3 | c.1220T>C p.I407T | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- CEP76 | c.1749A>G p.I583M | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.117); called by muse, varscan2
- CERS6 | c.550C>A p.L184M | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.098); called by muse, mutect2
- CFAP45 | c.860T>C p.L287P | Missense Mutation (SNP) | VAF 19/232 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CFAP53 | c.994del p.R332Efs*4 | Frame Shift Del (DEL) | VAF 56/206 reads (27%) | called by mutect2, pindel
- CFH | c.2365C>T p.H789Y | Missense Mutation (SNP) | VAF 41/297 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- CHD1 | c.1847C>T p.A616V | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHD5 | c.4036C>T p.R1346C | Missense Mutation (SNP) | VAF 21/412 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- CHD6 | c.5318A>G p.N1773S | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHD7 | c.3059del p.L1020* | Frame Shift Del (DEL) | VAF 27/338 reads (8%) | called by mutect2, pindel
- CHD9 | c.2280del p.F760Lfs*16 | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | called by mutect2, pindel
- CHRM2 | c.347T>C p.I116T | Missense Mutation (SNP) | VAF 159/603 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- CHRNB4 | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CLTC | c.3403_3406del p.S1135Pfs*19 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | called by pindel, varscan2
- CNGB3 | c.1591C>T p.Q531* | Nonsense Mutation (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- COL17A1 | c.464G>T p.W155L | Missense Mutation (SNP) | VAF 76/509 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL4A4 | c.1505dup p.G503Wfs*12 | Frame Shift Ins (INS) | VAF 36/311 reads (12%) | called by mutect2, pindel
- COL6A2 | c.736T>C p.C246R | Missense Mutation (SNP) | VAF 63/683 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- CPA1 | c.497del p.G166Afs*125 | Frame Shift Del (DEL) | VAF 55/336 reads (16%) | called by mutect2, pindel, varscan2
- CPNE8 | c.1189A>G p.M397V | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.85); PolyPhen benign (0.026); called by muse, mutect2
- CRIM1 | c.2567del p.P856Lfs*67 | Frame Shift Del (DEL) | VAF 22/184 reads (12%) | called by mutect2, pindel, varscan2
- CRYBB3 | c.404A>G p.D135G | Missense Mutation (SNP) | VAF 100/318 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSRP2 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | called by mutect2, varscan2
- CTC1 | c.3194A>G p.Q1065R | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.343); called by muse, mutect2
- CUL4B | c.923del p.L308Cfs*30 | Frame Shift Del (DEL) | VAF 18/140 reads (13%) | called by mutect2, varscan2
- CUX1 | c.3325_3326del p.S1109Rfs*54 | Frame Shift Del (DEL) | VAF 120/399 reads (30%) | called by pindel, varscan2
- CYBB | c.462T>A p.N154K | Missense Mutation (SNP) | VAF 31/266 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- CYLC2 | c.630del p.G211Efs*22 | Frame Shift Del (DEL) | VAF 25/97 reads (26%) | called by mutect2, pindel, varscan2
- DAP3 | c.684G>T p.Q228H | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DCST2 | c.156del p.W53Gfs*71 | Frame Shift Del (DEL) | VAF 89/515 reads (17%) | called by mutect2, pindel, varscan2
- DEPTOR | c.1059G>T p.Q353H | Missense Mutation (SNP) | VAF 25/277 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- DHX36 | c.2211A>C p.K737N | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DHX36 | c.1844A>G p.Y615C | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- DIP2C | c.2485G>A p.V829M | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DISC1 | c.1398+2T>C p.X466_splice | Splice Site (SNP) | VAF 87/555 reads (16%) | called by muse, mutect2, varscan2
- DLG5 | c.1667G>A p.S556N | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- DMXL2 | c.6834-2A>G p.X2278_splice | Splice Site (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2
- DNAH17 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 74/227 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- DNAJC19 | c.348del p.K116Nfs*6 | Frame Shift Del (DEL) | VAF 26/79 reads (33%) | called by mutect2, pindel, varscan2
- DNM1L | c.580T>C p.S194P | Missense Mutation (SNP) | VAF 97/305 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK3 | c.3364A>G p.M1122V | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- DOCK3 | c.5554_5555del p.P1852Sfs*46 | Frame Shift Del (DEL) | VAF 24/88 reads (27%) | called by pindel, varscan2
- DTL | c.525del p.D176Mfs*7 | Frame Shift Del (DEL) | VAF 42/271 reads (15%) | called by pindel, varscan2
- DTNA | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 41/379 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- DZIP1L | c.1808del p.P603Lfs*8 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel
- EFCAB8 | c.1997G>A p.G666D | Missense Mutation (SNP) | VAF 88/272 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- EFEMP2 | c.683G>A p.C228Y | Missense Mutation (SNP) | VAF 163/540 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EGR3 | c.472del p.V158Cfs*33 | Frame Shift Del (DEL) | VAF 24/254 reads (9%) | called by mutect2, pindel
- EI24 | c.677T>A p.I226N | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- ELF4 | c.139C>T p.H47Y | Missense Mutation (SNP) | VAF 129/530 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- ELL | c.1443del p.G482Efs*9 | Frame Shift Del (DEL) | VAF 43/145 reads (30%) | called by mutect2, pindel, varscan2
- EMB | c.740A>G p.E247G | Missense Mutation (SNP) | VAF 45/330 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- ENTPD5 | c.487A>G p.S163G | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.229); called by muse, varscan2
- EPB41L4A | c.1858del p.T620Qfs*9 | Frame Shift Del (DEL) | VAF 58/190 reads (31%) | called by mutect2, pindel, varscan2
- EPB41L4B | c.443del p.K148Sfs*3 | Frame Shift Del (DEL) | VAF 9/105 reads (9%) | called by mutect2, pindel
- EPGN | c.229C>A p.H77N | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- EPHA2 | c.2552T>C p.M851T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- EPRS1 | c.2131C>T p.P711S | Missense Mutation (SNP) | VAF 41/355 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.057); called by muse, varscan2
- EPYC | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ERICH3 | c.3566_3567del p.E1189Afs*13 | Frame Shift Del (DEL) | VAF 44/175 reads (25%) | called by pindel, varscan2
- ESRP1 | c.1534_1535del p.N512Hfs*7 | Frame Shift Del (DEL) | VAF 43/238 reads (18%) | called by pindel, varscan2*
- ETV6 | c.449A>G p.Q150R | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EXOC6 | c.611del p.L204Wfs*11 | Frame Shift Del (DEL) | VAF 30/164 reads (18%) | called by mutect2, pindel, varscan2
- EXOC8 | c.1823A>G p.D608G | Missense Mutation (SNP) | VAF 11/227 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2
- FAM25G | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 60/297 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- FANCE | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 191/707 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FANCI | c.2048T>C p.I683T | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAP | c.1036T>C p.W346R | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- FASN | c.4057del p.L1353Sfs*20 | Frame Shift Del (DEL) | VAF 96/362 reads (27%) | called by mutect2, varscan2
- FAT2 | c.2900G>A p.G967D | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBXL18 | c.1538G>A p.C513Y | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- FCRL2 | c.677G>A p.C226Y | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FHOD3 | c.1289del p.P430Hfs*44 | Frame Shift Del (DEL) | VAF 31/109 reads (28%) | called by mutect2, pindel, varscan2
- FITM1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 22/81 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FKBP4 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 88/408 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.013); called by muse, varscan2
- FLNB | c.4355T>C p.L1452P | Missense Mutation (SNP) | VAF 77/266 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- FOXA2 | c.1324A>G p.T442A (on ENST00000377115 / NM_153675.3; = p.T448A on NM_021784.5) | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FOXB2 | c.433del p.H145Tfs*193 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | called by pindel, varscan2
- FOXP1 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 102/432 reads (24%) | called by muse, mutect2, varscan2
- FRA10AC1 | c.741del p.K247Nfs*81 | Frame Shift Del (DEL) | VAF 11/56 reads (20%) | called by mutect2, pindel, varscan2
- FURIN | c.1703T>G p.L568R | Missense Mutation (SNP) | VAF 70/227 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- GCC1 | c.1237T>G p.S413A | Missense Mutation (SNP) | VAF 97/273 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- GCC2 | c.941A>G p.Q314R | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GEMIN5 | c.2196del p.K732Nfs*18 | Frame Shift Del (DEL) | VAF 36/248 reads (15%) | called by mutect2, pindel, varscan2
- GIMAP4 | c.50C>G p.A17G | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GJA5 | c.897G>T p.E299D | Missense Mutation (SNP) | VAF 151/911 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- GLI2 | c.355del p.H119Tfs*4 | Frame Shift Del (DEL) | VAF 16/98 reads (16%) | called by mutect2, pindel, varscan2
- GOLGB1 | c.3595A>T p.R1199* | Nonsense Mutation (SNP) | VAF 21/180 reads (12%) | called by muse, mutect2, varscan2
- GPATCH8 | c.1135del p.R379Gfs*2 | Frame Shift Del (DEL) | VAF 85/351 reads (24%) | called by mutect2, pindel, varscan2
- GPR179 | c.3869del p.K1290Rfs*12 (on ENST00000621958; = p.K1289Rfs*12 on NM_001004334.4) | Frame Shift Del (DEL) | VAF 40/172 reads (23%) | called by mutect2, varscan2
- GPR25 | c.820del p.A274Rfs*? | Frame Shift Del (DEL) | VAF 69/413 reads (17%) | called by mutect2, pindel, varscan2
- GPR26 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 21/312 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.018); called by muse, mutect2
- GRIA1 | c.2501G>T p.S834I | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRID1 | c.2095dup p.L699Pfs*9 | Frame Shift Ins (INS) | VAF 32/374 reads (9%) | called by mutect2, pindel
- GRIP2 | c.2684del p.G895Afs*24 (on ENST00000619221; = p.G798Afs*24 on NM_001080423.4) | Frame Shift Del (DEL) | VAF 28/100 reads (28%) | called by mutect2, pindel
- GRM5 | c.2425A>G p.S809G | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GSDMD | c.1275del p.L427Sfs*21 | Frame Shift Del (DEL) | VAF 15/108 reads (14%) | called by mutect2, pindel, varscan2
- GTDC1 | c.906dup p.K303* | Frame Shift Ins (INS) | VAF 24/103 reads (23%) | called by mutect2, varscan2
- GUCY2C | c.2698A>C p.I900L | Missense Mutation (SNP) | VAF 65/230 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- HAUS8 | c.842T>C p.V281A | Missense Mutation (SNP) | VAF 38/301 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HCN4 | c.2087A>G p.Y696C | Missense Mutation (SNP) | VAF 100/352 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HENMT1 | c.602A>T p.Y201F | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- HERC2 | c.12913C>A p.R4305S | Missense Mutation (SNP) | VAF 79/273 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HGFAC | c.1453T>C p.Y485H | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.039); called by muse, mutect2
- HIPK2 | c.524del p.N175Tfs*21 | Frame Shift Del (DEL) | VAF 123/421 reads (29%) | called by pindel, varscan2
- HLX | c.646C>A p.L216M | Missense Mutation (SNP) | VAF 66/305 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- HMCN1 | c.9902G>A p.G3301D | Missense Mutation (SNP) | VAF 88/598 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HPS4 | c.214_216del p.P72del | In Frame Del (DEL) | VAF 93/360 reads (26%) | called by pindel, varscan2
- HTT | c.9041C>T p.T3014I | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- IARS1 | c.1801del p.M601* | Frame Shift Del (DEL) | VAF 19/193 reads (10%) | called by mutect2, pindel
- IBTK | c.1745dup p.L582Ffs*6 | Frame Shift Ins (INS) | VAF 43/162 reads (27%) | called by mutect2, pindel, varscan2
- IFI44L | c.634A>G p.S212G | Missense Mutation (SNP) | VAF 43/239 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- IFNAR2 | c.1094A>G p.E365G | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2
- IGSF11 | c.403del p.V135Sfs*7 (on ENST00000393775 / NM_001015887.3; = p.V134Sfs*7 on NM_152538.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 36/187 reads (19%) | called by mutect2, pindel, varscan2
- IGSF22 | c.518G>T p.R173M | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2
- IGSF8 | c.1348G>T p.G450C | Missense Mutation (SNP) | VAF 55/365 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- IGSF8 | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 46/312 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL12B | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 140/536 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL1R1 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- INF2 | c.1587del p.V530Wfs*28 | Frame Shift Del (DEL) | VAF 23/141 reads (16%) | called by mutect2, pindel, varscan2
- INPP1 | c.819A>C p.K273N | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- INPPL1 | c.2709del p.S904Lfs*54 | Frame Shift Del (DEL) | VAF 19/207 reads (9%) | called by mutect2, pindel
- IRF2BP1 | c.749A>T p.H250L | Missense Mutation (SNP) | VAF 36/283 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- ITGB2 | c.742-2A>G p.X248_splice | Splice Site (SNP) | VAF 35/168 reads (21%) | called by muse, mutect2, varscan2
- ITPRID1 | c.3112A>C p.K1038Q | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2
- JAKMIP1 | c.405G>T p.E135D | Missense Mutation (SNP) | VAF 66/237 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KAT7 | c.242A>G p.Q81R | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCTD15 | c.848A>G p.D283G | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- KIAA2026 | c.1803dup p.G602Wfs*5 | Frame Shift Ins (INS) | VAF 35/179 reads (20%) | called by mutect2, pindel, varscan2
- KIF1B | c.3863A>G p.Q1288R (on ENST00000377086 / NM_001365952.1; = p.Q1242R on NM_015074.3) | Missense Mutation (SNP) | VAF 105/458 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF2C | c.201A>C p.E67D | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIFC1 | c.2012A>G p.N671S | Missense Mutation (SNP) | VAF 32/302 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- KLHL34 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- KMT2B | c.8122A>C p.K2708Q | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2
- KMT2D | c.7548del p.N2517Ifs*26 | Frame Shift Del (DEL) | VAF 23/89 reads (26%) | called by mutect2, pindel, varscan2
- KRT85 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 171/677 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- KRTAP10-10 | c.124T>A p.C42S | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- KRTAP10-12 | c.610A>G p.R204G | Missense Mutation (SNP) | VAF 60/454 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- KRTAP13-1 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP16-1 | c.1432C>A p.P478T | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- LACTBL1 | c.337T>G p.F113V (on ENST00000618559; = p.F142V on NM_001289974.2) | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2
- LAMB2 | c.3446G>T p.G1149V | Missense Mutation (SNP) | VAF 140/510 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LCORL | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LEXM | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 74/303 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- LGI3 | c.1229A>G p.Q410R | Missense Mutation (SNP) | VAF 51/502 reads (10%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.973); called by muse, mutect2
- LHX2 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 17/225 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.055); called by muse, mutect2
- LILRB5 | c.1460A>G p.K487R (on ENST00000449561 / NM_001081442.3; = p.K486R on NM_006840.5) | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LPA | c.147C>G p.C49W | Missense Mutation (SNP) | VAF 144/482 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRBA | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- LRFN1 | c.289_290del p.S97Pfs*61 | Frame Shift Del (DEL) | VAF 67/264 reads (25%) | called by pindel, varscan2
- LRIT2 | c.13T>G p.F5V | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- LRP8 | c.2708C>T p.A903V | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- LRRK2 | c.1403A>G p.H468R | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, varscan2
- LYST | c.9785-5del | Splice Region (DEL) | VAF 14/126 reads (11%) | called by mutect2, pindel, varscan2
- MAGEL2 | c.2587del p.Q863Rfs*41 | Frame Shift Del (DEL) | VAF 69/240 reads (29%) | called by mutect2, pindel, varscan2
- MAP1B | c.5901del p.E1968Kfs*2 | Frame Shift Del (DEL) | VAF 77/260 reads (30%) | called by mutect2, pindel, varscan2
- MAP4K5 | c.1155del p.K385Nfs*14 | Frame Shift Del (DEL) | VAF 25/77 reads (32%) | called by mutect2, pindel, varscan2
- MAP7 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- MARK2 | c.1989C>A p.D663E (on ENST00000402010 / NM_001039469.2; = p.D599E on NM_004954.5) | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MBTD1 | c.1296T>G p.C432W | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCOLN1 | c.32-1G>T p.X11_splice | Splice Site (SNP) | VAF 81/267 reads (30%) | called by muse, mutect2, varscan2
- MED13 | c.5329G>A p.G1777R | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED16 | c.2316G>T p.R772S | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MED24 | c.1535T>A p.I512N | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- MEF2D | c.1118C>A p.P373Q | Missense Mutation (SNP) | VAF 59/388 reads (15%) | SIFT tolerated (0.89); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MEGF8 | c.5857del p.R1953Afs*90 (on ENST00000251268 / NM_001271938.2; = p.R1886Afs*90 on NM_001410.3) | Frame Shift Del (DEL) | VAF 100/339 reads (29%) | called by mutect2, pindel, varscan2
- METTL21C | c.46del p.E16Kfs*10 | Frame Shift Del (DEL) | VAF 39/135 reads (29%) | called by mutect2, pindel, varscan2
- MEX3D | c.1360G>A p.G454S | Missense Mutation (SNP) | VAF 45/254 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- MFSD2B | c.408dup p.F137Lfs*263 | Frame Shift Ins (INS) | VAF 35/391 reads (9%) | called by mutect2, pindel
- MGARP | c.212A>G p.Q71R | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- MIA3 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MID1 | c.527T>A p.L176* | Nonsense Mutation (SNP) | VAF 78/636 reads (12%) | called by muse, mutect2, varscan2
- MLH3 | c.2021del p.N674Ifs*6 | Frame Shift Del (DEL) | VAF 40/125 reads (32%) | called by mutect2, varscan2
- MMP2 | c.1124G>A p.C375Y | Missense Mutation (SNP) | VAF 94/323 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MNX1 | c.902del p.K301Rfs*51 | Frame Shift Del (DEL) | VAF 57/486 reads (12%) | called by mutect2, pindel, varscan2
- MORC4 | c.2303_2304dup p.L769Sfs*5 | Frame Shift Ins (INS) | VAF 28/194 reads (14%) | called by mutect2, varscan2
- MPDZ | c.2296del p.E766Kfs*3 | Frame Shift Del (DEL) | VAF 69/269 reads (26%) | called by mutect2, pindel, varscan2
- MROH5 | c.1911A>G p.I637M | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MRPL2 | c.727A>G p.T243A | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MRPL20 | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 35/324 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- MTCL1 | c.4200del p.F1401Sfs*76 (on ENST00000306329 / NM_001378206.1; = p.F1082Sfs*76 on NM_015210.4) | Frame Shift Del (DEL) | VAF 8/115 reads (7%) | called by mutect2, pindel
- MTMR11 | c.1714del p.L572* (on ENST00000439741 / NM_001145862.2; = p.L500* on NM_181873.3) | Frame Shift Del (DEL) | VAF 32/352 reads (9%) | called by mutect2, pindel
- MTSS1 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MTUS1 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 54/265 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC3A | c.644T>C p.F215S | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious, low confidence (0.04); called by muse, mutect2
- MYCL | c.120dup p.T41Hfs*53 (on ENST00000372816 / NM_001033081.3; = p.T71Hfs*53 on NM_005376.5) | Frame Shift Ins (INS) | VAF 23/93 reads (25%) | called by mutect2, pindel, varscan2
- MYH1 | c.2723G>T p.R908M | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MYH16 | n.2659+1del | Splice Site (DEL) | VAF 18/68 reads (26%) | called by mutect2, pindel
- MYOCD | c.684del p.S229Afs*4 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | called by mutect2, pindel, varscan2
- NCAPG | c.1984del p.I662Sfs*11 | Frame Shift Del (DEL) | VAF 39/116 reads (34%) | called by mutect2, pindel, varscan2
- NDST4 | c.20T>G p.L7R | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NEK3 | c.419A>G p.K140R | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NFASC | c.2639C>A p.P880H (on ENST00000339876 / NM_001378329.1; = p.P983H on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/482 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- NFIC | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 28/394 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NFX1 | c.532T>C p.Y178H | Missense Mutation (SNP) | VAF 52/301 reads (17%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NGFR | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 18/101 reads (18%) | called by muse, mutect2, varscan2
- NLRP10 | c.1322C>A p.P441H | Missense Mutation (SNP) | VAF 68/258 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- NOL4L | c.1201C>A p.P401T | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- NOP58 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2
- NPHS1 | c.1774G>A p.A592T | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NRIP2 | c.671A>T p.E224V | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.159); called by muse, mutect2
- NSD1 | c.4405A>G p.R1469G | Missense Mutation (SNP) | VAF 140/419 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- NT5E | c.776C>A p.P259H | Missense Mutation (SNP) | VAF 98/379 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NTPCR | c.16T>C p.F6L | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- NUDT16L1 | c.251T>C p.L84P | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NUP54 | c.390G>T p.L130F | Missense Mutation (SNP) | VAF 107/348 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OAT | c.97del p.T33Qfs*28 | Frame Shift Del (DEL) | VAF 105/550 reads (19%) | called by pindel, varscan2
- OBSCN | c.5026G>A p.A1676T | Missense Mutation (SNP) | VAF 70/869 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); called by muse, mutect2
- ODF3L2 | c.25A>G p.T9A | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- OPRK1 | c.163T>G p.S55A | Missense Mutation (SNP) | VAF 71/277 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OPRL1 | c.697G>C p.V233L | Missense Mutation (SNP) | VAF 43/363 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- OR1I1 | c.46G>T p.G16* | Nonsense Mutation (SNP) | VAF 9/94 reads (10%) | called by muse, mutect2
- OR2C3 | c.683A>T p.K228M | Missense Mutation (SNP) | VAF 61/372 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- OR2T27 | c.174del p.M59Cfs*28 | Frame Shift Del (DEL) | VAF 22/180 reads (12%) | called by mutect2, varscan2
- OR4A47 | c.615C>A p.C205* | Nonsense Mutation (SNP) | VAF 20/155 reads (13%) | called by muse, mutect2, varscan2
- OR51I1 | c.24del p.F9Sfs*8 | Frame Shift Del (DEL) | VAF 33/105 reads (31%) | called by mutect2, pindel, varscan2
- OR5B21 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR5M8 | c.418_419del p.C140Lfs*32 | Frame Shift Del (DEL) | VAF 48/294 reads (16%) | called by pindel, varscan2
- OR5T2 | c.461T>A p.L154* | Nonsense Mutation (SNP) | VAF 36/223 reads (16%) | called by muse, mutect2, varscan2
- OR8G1 | c.715A>G p.S239G | Missense Mutation (SNP) | VAF 23/331 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.248); called by muse, mutect2
- PANK3 | c.493A>T p.N165Y | Missense Mutation (SNP) | VAF 86/343 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PAQR5 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 68/335 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- PCDH8 | c.635G>A p.S212N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- PDE1A | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.618); called by muse, mutect2
- PDGFRA | c.2438dup p.N813Kfs*6 | Frame Shift Ins (INS) | VAF 68/406 reads (17%) | called by pindel, varscan2
- PDZD7 | c.2888C>T p.A963V | Missense Mutation (SNP) | VAF 49/528 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2
- PGAP6 | c.1758C>T p.F586= | Splice Region (SNP) | VAF 52/186 reads (28%) | called by muse, mutect2, varscan2
- PHF10 | c.328T>G p.L110V | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- PHF2 | c.2144C>A p.P715H | Missense Mutation (SNP) | VAF 57/215 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIAS2 | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | called by mutect2, varscan2
- PIAS4 | c.35T>C p.V12A | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, varscan2
- PIGQ | c.1379T>C p.L460P | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PIK3AP1 | c.1865T>C p.V622A | Missense Mutation (SNP) | VAF 86/387 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PITPNM2 | c.1080dup p.K361Qfs*10 | Frame Shift Ins (INS) | VAF 30/291 reads (10%) | called by mutect2, pindel, varscan2
- PKD1 | c.10294A>G p.S3432G (on ENST00000262304 / NM_001009944.3; = p.S3431G on NM_000296.4) | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PKD2 | c.2118G>T p.K706N | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- PKP3 | c.999dup p.N334Qfs*32 | Frame Shift Ins (INS) | VAF 46/195 reads (24%) | called by mutect2, pindel, varscan2
- PLCB2 | c.1301C>T p.T434I | Missense Mutation (SNP) | VAF 78/286 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- PLEKHA5 | c.1430del p.P477Lfs*8 | Frame Shift Del (DEL) | VAF 44/376 reads (12%) | called by mutect2, pindel, varscan2
- PLEKHA6 | c.1829T>C p.L610P | Missense Mutation (SNP) | VAF 60/384 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PLEKHH2 | c.2720A>G p.K907R | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLPPR5 | c.195del p.V66Cfs*14 | Frame Shift Del (DEL) | VAF 35/146 reads (24%) | called by mutect2, pindel, varscan2
- PMS2 | c.537G>T p.K179N | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POMC | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 68/318 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- POR | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- POU5F1 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 66/286 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPFIA2 | c.2157del p.S720Vfs*23 | Frame Shift Del (DEL) | VAF 22/159 reads (14%) | called by mutect2, varscan2
- PPP1R10 | c.2066del p.G689Vfs*228 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- PPP1R13L | c.1947+1G>T p.X649_splice | Splice Site (SNP) | VAF 22/92 reads (24%) | called by muse, mutect2, varscan2
- PPRC1 | c.3152_3153del p.E1051Afs*37 | Frame Shift Del (DEL) | VAF 56/259 reads (22%) | called by pindel, varscan2
- PRDM13 | c.566G>A p.G189D | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM2 | c.3527A>T p.D1176V | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PRDM7 | c.478A>G p.T160A | Missense Mutation (SNP) | VAF 68/283 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PRICKLE2 | c.2384G>T p.G795V (on ENST00000295902; = p.G739V on NM_198859.4) | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PRRC2A | c.4817T>C p.L1606P | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- PRSS36 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRQ | c.4140A>C p.S1380= (on ENST00000616559; = p.S1338= on NM_001145026.2) | Splice Region (SNP) | VAF 18/170 reads (11%) | called by muse, mutect2
- PUM2 | c.850T>A p.Y284N | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PUS1 | c.893T>C p.V298A | Missense Mutation (SNP) | VAF 87/519 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- PXDN | c.3569del p.N1190Mfs*12 | Frame Shift Del (DEL) | VAF 14/125 reads (11%) | called by mutect2, pindel, varscan2
- R3HCC1L | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 59/269 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- RAB3GAP2 | c.4006T>C p.C1336R | Missense Mutation (SNP) | VAF 27/869 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2
- RABL2A | c.172C>A p.L58M | Missense Mutation (SNP) | VAF 35/420 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.934); called by muse, mutect2
- RARG | c.199_200del p.S67Hfs*28 | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | called by pindel, varscan2
- RASGRF1 | c.3344C>T p.A1115V | Missense Mutation (SNP) | VAF 36/309 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- RBFOX1 | c.1182dup p.A395Cfs*35 | Frame Shift Ins (INS) | VAF 18/78 reads (23%) | called by mutect2, pindel, varscan2
- RBFOX3 | c.850A>G p.S284G | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- RC3H1 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 115/647 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- RFX7 | c.2754del p.S919Afs*14 (on ENST00000559447 / NM_001368074.1; = p.S1016Afs*14 on NM_022841.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 52/165 reads (32%) | called by mutect2, pindel, varscan2
- RIC1 | c.897T>G p.Y299* | Nonsense Mutation (SNP) | VAF 28/92 reads (30%) | called by muse, mutect2, varscan2
- RNASE7 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RNF126 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ROR2 | c.2081G>A p.C694Y | Missense Mutation (SNP) | VAF 75/599 reads (13%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPLP0 | c.181A>C p.M61L | Missense Mutation (SNP) | VAF 9/213 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.088); called by muse, mutect2
- RPS6KA4 | c.2039_2040del p.R680Lfs*123 | Frame Shift Del (DEL) | VAF 43/184 reads (23%) | called by pindel, varscan2
- RREB1 | c.3673A>G p.S1225G | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- RTTN | c.4459del p.Y1487Mfs*4 | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | called by mutect2, pindel, varscan2
- RTTN | c.827del p.F276Sfs*69 | Frame Shift Del (DEL) | VAF 13/96 reads (14%) | called by mutect2, pindel, varscan2
- RUFY1 | c.1574A>C p.E525A | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- RWDD2A | c.839A>G p.Q280R | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.3); called by mutect2, varscan2
- RXRB | c.992G>A p.S331N | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.558); called by muse, mutect2
- SALL1 | c.2686dup p.D896Gfs*6 | Frame Shift Ins (INS) | VAF 45/190 reads (24%) | called by mutect2, pindel, varscan2
- SAMD15 | c.1936G>T p.E646* | Nonsense Mutation (SNP) | VAF 17/206 reads (8%) | called by muse, mutect2
- SBF1 | c.1586del p.P529Qfs*3 | Frame Shift Del (DEL) | VAF 16/99 reads (16%) | called by mutect2, pindel, varscan2
- SBK3 | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); called by muse, mutect2
- SBNO2 | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 77/318 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCRIB | c.641del p.P214Rfs*52 | Frame Shift Del (DEL) | VAF 14/123 reads (11%) | called by mutect2, pindel
- SCTR | c.1209G>A p.W403* | Nonsense Mutation (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- SENP7 | c.2583G>A p.W861* | Nonsense Mutation (SNP) | VAF 28/127 reads (22%) | called by muse, mutect2, varscan2
- SERPINF2 | c.335G>A p.S112N | Missense Mutation (SNP) | VAF 17/429 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SETD5 | c.3937C>A p.P1313T | Missense Mutation (SNP) | VAF 67/256 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SFMBT2 | c.2042C>A p.P681H | Missense Mutation (SNP) | VAF 53/256 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- SHC1 | c.18del p.K7Sfs*59 | Frame Shift Del (DEL) | VAF 16/135 reads (12%) | called by pindel, varscan2
- SHKBP1 | c.430A>G p.S144G | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SHPRH | c.277del p.S93Pfs*5 | Frame Shift Del (DEL) | VAF 19/142 reads (13%) | called by pindel, varscan2
- SHROOM4 | c.48del p.A19Hfs*34 | Frame Shift Del (DEL) | VAF 33/325 reads (10%) | called by mutect2, pindel, varscan2
- SIX5 | c.1048C>A p.L350M | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- SLC20A2 | c.613+2T>C p.X205_splice | Splice Site (SNP) | VAF 15/106 reads (14%) | called by muse, mutect2, varscan2
- SLC35C2 | c.834del p.F278Lfs*21 | Frame Shift Del (DEL) | VAF 38/156 reads (24%) | called by mutect2, pindel, varscan2
- SLC41A1 | c.1058C>T p.T353M | Missense Mutation (SNP) | VAF 140/842 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SLC44A3 | c.240_241insT p.G81Wfs*42 (on ENST00000271227 / NM_001114106.3; = p.G33Wfs*42 on NM_152369.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 12/98 reads (12%) | called by mutect2, pindel, varscan2
- SLC47A1 | c.815T>C p.M272T | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2
- SLC6A13 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 88/288 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- SLC9B2 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.062); called by muse, mutect2
- SLCO2B1 | c.698T>C p.V233A | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.106); called by muse, varscan2
- SLIT1 | c.2638T>G p.W880G | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2
- SMAD4 | c.1493T>C p.L498S | Missense Mutation (SNP) | VAF 122/422 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMG1 | c.5468T>C p.I1823T | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- SMG5 | c.2720G>A p.R907Q | Missense Mutation (SNP) | VAF 71/407 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SMG7 | c.2564A>C p.E855A | Missense Mutation (SNP) | VAF 80/392 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SMURF1 | c.2083T>G p.L695V | Missense Mutation (SNP) | VAF 66/230 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2
- SNRNP200 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 111/384 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- SNX16 | c.209G>A p.S70N | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- SNX17 | c.243G>C p.K81N | Missense Mutation (SNP) | VAF 85/239 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SORBS2 | c.1507dup p.R503Pfs*27 | Frame Shift Ins (INS) | VAF 60/266 reads (23%) | called by mutect2, pindel, varscan2
- SOX6 | c.2284T>C p.C762R (on ENST00000528429 / NM_001145819.2; = p.C735R on NM_017508.3) | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.157); called by muse, mutect2, varscan2
477 further variants in this file (96 protein-altering or splice-affecting, 221 silent, 160 other) are not listed here.
